Somatic mutation profile of tumor specimen TCGA-GU-A767-01A (aliquot TCGA-GU-A767-01A-11D-A32B-08) from TCGA case TCGA-GU-A767, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 81.4 years (29,739 days).
Specimen TCGA-GU-A767-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1651f55-fc95-44b6-945a-9b93693f035d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GU-A767-10A (Blood Derived Normal), aliquot TCGA-GU-A767-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ac2a51e-a207-4755-9a49-e3bc600760af

The open-access MAF lists 409 somatic variants for this specimen: 309 protein-altering or splice-affecting, 88 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 268, Silent 88, Nonsense Mutation 25, Intron 6, RNA 5, Splice Site 4, Frame Shift Del 4, Splice Region 3, Frame Shift Ins 2, 3'UTR 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.1300C>T p.R434* (on ENST00000272895 / NM_173076.3; = p.R116* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as rs757520757, CM052164, COSV99791006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 16/317 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2
- KMT2D | c.15943C>T p.Q5315* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs587783699, COSV56413658, COSV99983362; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RHOA | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV69041798; called by muse, mutect2, varscan2
- ABCA3 | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV57057225; called by muse, mutect2, varscan2
- ABCB8 | c.386G>C p.G129A (on ENST00000297504 / NM_001282291.2; = p.G112A on NM_007188.5) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV52508086, COSV52509930; called by muse, mutect2, varscan2
- AC004922.1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV53558366; called by muse, mutect2, varscan2
- AC020907.6 | c.49G>C p.V17L | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.054); catalogued as COSV59534384; called by muse, mutect2
- ACTN3 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138699570; called by muse, mutect2, varscan2
- ADAMTS4 | c.1957G>T p.V653F | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63490843; called by muse, mutect2, varscan2
- ADGRG4 | c.3068C>G p.S1023C | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV54962630; called by muse, mutect2, varscan2
- ADGRG5 | c.1268C>T p.T423M | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as rs761981384, COSV61083359; called by muse, mutect2, varscan2
- ALMS1 | c.3785C>T p.A1262V | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV52516634; called by muse, mutect2
- AMOTL2 | c.989G>C p.R330P | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.415); catalogued as COSV51440152; called by muse, mutect2, varscan2
- ANK2 | c.2240T>C p.L747P | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52177263; called by muse, mutect2
- ARFGAP3 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as rs765083530, COSV54313439; called by muse, mutect2, varscan2
- ARHGAP31 | c.432-1G>C p.X144_splice | Splice Site (SNP) | VAF 10/127 reads (8%) | catalogued as COSV51792671, COSV51796654; called by muse, mutect2
- ASZ1 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV52915085; called by muse, mutect2
- ATP2C2 | c.1794G>A p.M598I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs747575746, COSV52294026, COSV52299192; called by muse, mutect2, varscan2
- ATRIP | c.1514C>A p.A505D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.165); catalogued as COSV56497657; called by muse, mutect2, varscan2
- AXDND1 | c.960A>T p.L320F | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV62645671; called by muse, mutect2, varscan2
- BAG4 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV54861386; called by muse, mutect2, varscan2
- BBX | c.83G>C p.W28S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV57890436; called by muse, mutect2, varscan2
- BCAR1 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.535); catalogued as COSV50793094; called by muse, mutect2, varscan2
- BCAS3 | c.1050T>A p.H350Q | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66778565; called by muse, mutect2
- BIVM-ERCC5 | c.2957C>T p.S986F | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs570775554, COSV63246339; called by muse, mutect2, varscan2
- BLM | c.2762G>T p.G921V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61925927; called by muse, mutect2, varscan2
- BORCS7 | c.206G>A p.S69N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.172); catalogued as COSV100185798; called by muse, mutect2
- BRINP1 | c.2101G>A p.D701N | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV56307545, COSV56307711; called by muse, mutect2, varscan2
- BRPF3 | c.776G>A p.C259Y | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60208762; called by muse, mutect2, varscan2
- C2orf16 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as COSV68842133; called by muse, mutect2, varscan2
- C6orf118 | c.918G>T p.Q306H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV57814393, COSV57817227; called by muse, mutect2, varscan2
- CA10 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs1046164022, COSV53350094; called by muse, mutect2
- CABIN1 | c.1314A>T p.E438D | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.97); catalogued as COSV99573658; called by muse, mutect2
- CASK | c.1221G>C p.Q407H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV59372155; called by muse, mutect2, varscan2
- CBX7 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV53359530; called by muse, mutect2
- CCDC7 | c.2441G>A p.R814K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.82); PolyPhen benign (0.39); catalogued as rs779447340, COSV56548432; called by muse, mutect2, varscan2
- CCDC92 | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV53020939; called by muse, mutect2, varscan2
- CCT2 | c.1570G>T p.A524S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV54740989; called by muse, mutect2, varscan2
- CDC14A | c.1646G>T p.S549I | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.073); catalogued as COSV60561158; called by muse, mutect2, varscan2
- CDC42BPB | c.3341G>C p.W1114S | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63476163; called by muse, mutect2, varscan2
- CDH8 | c.1133T>G p.V378G | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54885525; called by muse, mutect2, varscan2
- CDKAL1 | c.1369C>G p.Q457E | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV51187251; called by muse, mutect2, varscan2
- CES1 | c.660G>T p.E220D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV62088934; called by muse, mutect2, varscan2
- CETN1 | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.274); catalogued as rs774387355, COSV59121888; called by muse, mutect2, varscan2
- CFAP65 | c.1055G>A p.C352Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV55391089; called by muse, mutect2, varscan2
- CHMP6 | c.562G>T p.V188F | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV57327790; called by muse, mutect2, varscan2
- CHRND | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV51322050; called by muse, mutect2, varscan2
- CNTF | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60160795; called by muse, mutect2
- CNTN5 | c.1852G>T p.E618* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as COSV99679151; called by muse, mutect2, varscan2
- CNTNAP5 | c.1430G>T p.S477I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1419020128, COSV101443836; called by muse, mutect2
- COG1 | c.2272C>T p.R758W | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs146952271, COSV55431076; called by muse, mutect2, varscan2
- COG8 | c.641A>G p.Q214R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); catalogued as COSV54743037; called by muse, mutect2, varscan2
- COL11A1 | c.4141-1G>A p.X1381_splice | Splice Site (SNP) | VAF 3/35 reads (9%) | catalogued as COSV62195939; called by muse, mutect2
- COL12A1 | c.3929G>A p.G1310E | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59402509; called by muse, mutect2, varscan2
- COL14A1 | c.4314G>C p.L1438= | Splice Region (SNP) | VAF 14/49 reads (29%) | catalogued as COSV52862541; called by muse, mutect2, varscan2
- COL28A1 | c.1270G>T p.G424* | Nonsense Mutation (SNP) | VAF 18/97 reads (19%) | catalogued as COSV101258803, COSV101258827; called by muse, mutect2, varscan2
- COL6A6 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs777867254, COSV62025230; called by muse, mutect2, varscan2
- CPT2 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.772); catalogued as COSV53759973; called by muse, mutect2, varscan2
- CRX | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 28/85 reads (33%) | catalogued as COSV99704593; called by muse, mutect2, varscan2
- CTDSPL | c.772G>C p.E258Q (on ENST00000273179 / NM_001008392.2; = p.E247Q on NM_005808.3) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56203505, COSV99828966; called by muse, mutect2, varscan2
- CUL9 | c.6084G>C p.L2028F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52732058; called by muse, mutect2, varscan2
- CXCL17 | c.240C>G p.F80L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV59409215; called by muse, mutect2, varscan2
- CYB5D1 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1263949296, COSV54681435; called by muse, mutect2
- DCAF12 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 10/19 reads (53%) | catalogued as COSV100778386, COSV63513656; called by muse, mutect2, varscan2
- DCAF4 | c.535-1G>C p.X179_splice | Splice Site (SNP) | VAF 22/294 reads (7%) | catalogued as COSV62320172; called by muse, mutect2
- DENND4C | c.4805C>G p.S1602C (on ENST00000434457 / NM_001330640.2; = p.S1553C on NM_017925.7) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100727311, COSV63009382; called by muse, mutect2, varscan2
- DGKA | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.003); catalogued as rs529258657, COSV59387452; called by muse, mutect2, varscan2
- DISP3 | c.322T>A p.F108I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53833679; called by muse, mutect2, varscan2
- DLG5 | c.2879A>G p.K960R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.255); catalogued as COSV64949023; called by muse, mutect2, varscan2
- DMAC2 | c.624C>A p.D208E | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV55729179; called by muse, varscan2
- DOK3 | c.42C>A p.Y14* | Nonsense Mutation (SNP) | VAF 6/122 reads (5%) | catalogued as COSV100394434; called by muse, mutect2
- DPP10 | c.2223C>A p.H741Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.088); catalogued as COSV59706929; called by muse, mutect2, varscan2
- EIF3A | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as COSV100974690; called by muse, mutect2
- ENO1 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.261); catalogued as COSV52304870; called by muse, mutect2, varscan2
- EPB41L3 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as COSV59442719; called by muse, mutect2, varscan2
- EXTL3 | c.2736G>C p.K912N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV55039264; called by muse, mutect2, varscan2
- F2RL1 | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.667); catalogued as COSV56996363; called by muse, mutect2, varscan2
- FAM184A | c.3150G>T p.K1050N | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs376040804; called by muse, mutect2, varscan2
- FAM76A | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.053); catalogued as COSV50549517; called by muse, mutect2, varscan2
- FAM76A | c.787A>G p.K263E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99159472; called by muse, mutect2
- FBF1 | c.646G>A p.G216R (on ENST00000586717; = p.G230R on NM_001319193.1) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1320855851, COSV100045392; called by muse, mutect2
- FGFR4 | c.420C>A p.H140Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV52807507; called by muse, mutect2, varscan2
- FGFR4 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs962807397, COSV52807520; called by muse, mutect2, varscan2
- FGG | c.958G>C p.D320H | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV60195366, COSV60196193; called by muse, mutect2
- FLNB | c.2554G>A p.G852S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55888338; called by muse, mutect2, varscan2
- FLT4 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1164739687, COSV56116914; called by muse, mutect2, varscan2
- FOXJ3 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 9/213 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.038); catalogued as COSV62364089; called by muse, mutect2
- FRAS1 | c.5383G>C p.E1795Q | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV53630914, COSV99078042; called by muse, mutect2
- FZD7 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV53808382, COSV53810943; called by muse, mutect2
- GABRG1 | c.1314A>T p.K438N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV54958586; called by muse, mutect2, varscan2
- GAD2 | c.335A>T p.Q112L | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV52163603; called by muse, mutect2, varscan2
- GALR1 | c.938C>A p.A313D | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as COSV55318392; called by muse, mutect2, varscan2
- GJD2 | c.272T>G p.L91R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51749489; called by muse, mutect2, varscan2
- GLYR1 | c.606G>A p.W202* | Nonsense Mutation (SNP) | VAF 46/172 reads (27%) | catalogued as COSV58928458; called by muse, mutect2, varscan2
- GOLGB1 | c.4981G>A p.E1661K | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV61468669; called by muse, mutect2
- GON4L | c.2953G>A p.A985T | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV55199210; called by muse, mutect2, varscan2
- GPD1 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56548743; called by muse, mutect2, varscan2
- GPR141 | c.529T>A p.Y177N | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as COSV57733406; called by muse, mutect2, varscan2
- GRAMD1C | c.1226G>T p.S409I | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63982729, COSV63983568; called by muse, mutect2, varscan2
- GRM3 | c.665A>G p.Y222C | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64476530; called by muse, mutect2, varscan2
- H3-3A | c.194A>C p.K65T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); catalogued as COSV100831331; called by muse, mutect2
- H6PD | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as COSV66231719; called by muse, mutect2, varscan2
- HCRTR1 | c.1106T>C p.F369S | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV65484045; called by muse, mutect2, varscan2
- HIF3A | c.1291C>G p.P431A (on ENST00000377670 / NM_152795.4; = p.P362A on NM_022462.4) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV99355957; called by muse, mutect2
- HIVEP2 | c.2119G>C p.E707Q | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50031769; called by muse, mutect2
- HK1 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as rs1487404037; called by muse, mutect2
- HOXA4 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100415575; called by muse, mutect2
- HRH3 | c.1074G>T p.K358N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58049607; called by muse, mutect2
- HS3ST5 | c.268C>A p.L90I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV100450616, COSV100451129; called by muse, mutect2
- HSH2D | c.641G>A p.G214D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV53739015; called by muse, mutect2, varscan2
- IFT122 | c.3007G>T p.A1003S (on ENST00000348417 / NM_052989.3; = p.A944S on NM_018262.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV99959596; called by muse, mutect2
- IL4R | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV50156288; called by muse, mutect2, varscan2
- IMPDH2 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 21/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1194381242, COSV58708431, COSV58708572; called by muse, mutect2
- INO80 | c.2837A>G p.N946S | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV62740769; called by muse, mutect2
- IQGAP2 | c.4166C>G p.S1389C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV57171797, COSV57177931; called by muse, mutect2, varscan2
- IRF3 | c.758C>A p.T253K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV55864074; called by muse, mutect2, varscan2
- IRGQ | c.72C>G p.I24M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as COSV60670983, COSV60671165; called by muse, mutect2, varscan2
- ITGAE | c.2765C>G p.S922* | Nonsense Mutation (SNP) | VAF 4/73 reads (5%) | catalogued as COSV53995028, COSV99561549; called by muse, mutect2
- ITGAV | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV53716464; called by muse, mutect2, varscan2
- ITGB3 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as rs1282245056, COSV71384792; called by muse, mutect2, varscan2
- JOSD2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs374254320, COSV65350470; called by muse, mutect2, varscan2
- JPH4 | c.1714C>G p.L572V | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.522); catalogued as COSV100436866; called by muse, mutect2
- KALRN | c.19G>T p.D7Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.934); catalogued as COSV53774369; called by muse, mutect2, varscan2
- KAT8 | c.275A>C p.H92P | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54898191; called by muse, mutect2, varscan2
- KCNAB1 | c.670G>T p.A224S (on ENST00000490337 / NM_172160.3; = p.A213S on NM_003471.3) | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV56750309; called by muse, mutect2, varscan2
- KCNH3 | c.1603A>T p.K535* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99235519; called by muse, mutect2, varscan2
- KCNH6 | c.200A>T p.D67V | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV59006038; called by muse, mutect2, varscan2
- KCNJ6 | c.110G>T p.R37M | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as COSV99900101; called by muse, mutect2
- KCNK7 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs561549970, COSV58420108; called by muse, mutect2, varscan2
- KIAA1109 | c.5665G>T p.G1889* | Nonsense Mutation (SNP) | VAF 8/89 reads (9%) | catalogued as COSV99167761; called by muse, mutect2
- KLHDC7A | c.1411A>G p.I471V | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as rs1022128564, COSV68770507; called by muse, mutect2
- KLHL28 | c.919C>G p.Q307E | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100753194; called by muse, mutect2
- KLRG1 | c.174G>A p.W58* | Nonsense Mutation (SNP) | VAF 76/280 reads (27%) | catalogued as COSV56943437; called by muse, varscan2
- KMT2C | c.13394G>A p.C4465Y | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51475576; called by muse, mutect2, varscan2
- KMT5B | c.1337A>T p.K446M | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58568472; called by muse, mutect2, varscan2
- KPRP | c.40C>G p.Q14E | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV64222446; called by muse, mutect2, varscan2
- KRT34 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV67450344; called by muse, mutect2, varscan2
- KRT76 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.942); catalogued as rs1565673669, COSV60121331; called by muse, mutect2, varscan2
- KRTAP9-2 | c.122C>A p.A41D | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100893218; called by muse, mutect2
- LARGE2 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs151292942; called by muse, mutect2, varscan2
- LARP7 | c.1501G>C p.E501Q | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100135259; called by muse, mutect2
- LATS1 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1264217871, COSV53596119; called by muse, mutect2
- LATS1 | c.1378G>A p.V460M | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV53596145; called by muse, mutect2
- LCE1F | c.254C>A p.S85Y | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.991); catalogued as rs1557832513, COSV57669700; called by muse, mutect2, varscan2
- LHCGR | c.1772C>T p.S591L | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54300734; called by muse, mutect2, varscan2
- LLCFC1 | c.269C>T p.S90L (on ENST00000458732; = p.S59L on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV100787189; called by muse, mutect2
- LRRC25 | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV59115619; called by muse, mutect2
- LST1 | c.260C>A p.T87N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV53001923; called by muse, mutect2, varscan2
- MACF1 | c.21733A>T p.M7245L (on ENST00000372915; = p.M5290L on NM_012090.5) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as COSV57133893; called by muse, mutect2, varscan2
- MAN2B2 | c.2274G>A p.M758I | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV53455414; called by muse, mutect2, varscan2
- MBOAT2 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV60010721; called by muse, mutect2, varscan2
- MEDAG | c.431T>G p.I144R | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100995294; called by muse, mutect2
- MON2 | c.4403G>C p.R1468T | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV54811771; called by muse, mutect2
- MREG | c.165G>C p.M55I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54375013; called by muse, mutect2, varscan2
- MRPL33 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs750428922, COSV56088172; called by muse, mutect2, varscan2
- MUSK | c.808C>G p.L270V | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51891705; called by muse, mutect2, varscan2
- MYO9B | c.2714T>G p.L905R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101261719; called by muse, mutect2
- NBAS | c.5081G>C p.S1694T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs757665960, COSV55731526, COSV99872075; called by mutect2, varscan2
- NCOA6 | c.2715G>T p.K905N | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV62866079; called by muse, mutect2, varscan2
- NCOA7 | c.2747C>G p.S916C | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV57658011; called by muse, mutect2, varscan2
- NDC80 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1422789582, COSV55249046, COSV55249517, COSV99859918; called by muse, mutect2, varscan2
- NFATC3 | c.1593G>A p.M531I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60477059; called by muse, mutect2
- NFATC3 | c.1927C>T p.Q643* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV60475645; called by muse, mutect2, varscan2
- NID1 | c.3131G>A p.R1044Q | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs371251887, COSV99936884; called by muse, mutect2, varscan2
- NLRP5 | c.2553A>T p.E851D | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV66766318; called by muse, mutect2
- NOS3 | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as rs1363067747, COSV52493229; called by muse, mutect2, varscan2
- NTN4 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59221662, COSV59222219; called by muse, mutect2, varscan2
- OR10G8 | c.500A>T p.Y167F | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.107); catalogued as COSV70909015; called by muse, mutect2, varscan2
- OR4K2 | c.149T>C p.I50T | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs1366210614, COSV53850815; called by muse, mutect2, varscan2
- OR5AU1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV58615958; called by muse, mutect2, varscan2
- OR5H1 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100641741; called by muse, mutect2, varscan2
- OR5J2 | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV56620349, COSV56622503; called by muse, mutect2
- OR8D2 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV62488004; called by muse, mutect2
- OR8J3 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 5/133 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100040938, COSV56880685; called by muse, mutect2
- PABPC4 | c.858G>C p.E286D | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.029); catalogued as COSV63293568; called by muse, mutect2, varscan2
- PARD3 | c.2377G>T p.G793C | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.246); catalogued as COSV60756397; called by muse, mutect2, varscan2
- PCDHAC2 | c.841G>C p.A281P | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53861753, COSV53874934; called by muse, mutect2, varscan2
- PCDHB6 | c.13A>T p.K5* | Nonsense Mutation (SNP) | VAF 22/117 reads (19%) | catalogued as COSV50705815, COSV99170501; called by muse, mutect2, varscan2
- PCDHGA10 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53996462; called by muse, mutect2
- PCDHGA12 | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV52760454; called by muse, mutect2, varscan2
- PCDHGB4 | c.821A>T p.N274I | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53996446; called by muse, mutect2, varscan2
- PDE9A | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 57/302 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs147667334; called by muse, mutect2, varscan2
- PGBD1 | c.2195A>T p.Y732F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as COSV52555021; called by muse, mutect2, varscan2
- PGBD5 | c.1324G>C p.V442L (on ENST00000525115; = p.V511L on NM_001258311.2) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.222); catalogued as COSV58412799; called by muse, mutect2, varscan2
- PHACTR1 | c.795G>C p.K265N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.373); catalogued as COSV60675252; called by muse, mutect2, varscan2
- PIK3R2 | c.1381G>C p.D461H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55849341; called by muse, mutect2, varscan2
- PIKFYVE | c.2113C>A p.L705I | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52245911; called by muse, mutect2
- PITPNB | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs1393137074, COSV58062262; called by muse, mutect2, varscan2
- PITPNM2 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs142151554; called by muse, mutect2, varscan2
- PLD3 | c.1147G>T p.A383S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.241); catalogued as COSV52524026; called by muse, mutect2, varscan2
- PLEKHG6 | c.913T>G p.L305V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV50606526; called by muse, mutect2, varscan2
- PPARGC1A | c.997T>C p.Y333H | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV53531379; called by muse, mutect2, varscan2
- PPFIA3 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1233005037, COSV53257877; called by muse, mutect2, varscan2
- PPIP5K2 | c.3096G>A p.Q1032= | Splice Region (SNP) | VAF 4/82 reads (5%) | catalogued as COSV100384021; called by muse, mutect2
- PPM1J | c.1417C>A p.P473T | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV53518713; called by muse, mutect2, varscan2
- PPP1CA | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); catalogued as COSV56704287; called by muse, mutect2, varscan2
- PPP1R15B | c.1990G>T p.E664* | Nonsense Mutation (SNP) | VAF 7/102 reads (7%) | catalogued as COSV100916358; called by muse, mutect2
- PRDM10 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.888); catalogued as rs757411284, COSV58803587; called by muse, mutect2, varscan2
- PRH1 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 15/147 reads (10%) | catalogued as COSV70371822; called by muse, mutect2, varscan2
- PTN | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV100780950; called by muse, mutect2
- PTPDC1 | c.811C>T p.R271C (on ENST00000375360 / NM_177995.3; = p.R323C on NM_152422.4) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs141265646; called by muse, mutect2, varscan2
- PTPRE | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54555745; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3640A>C p.S1214R (on ENST00000330843 / NM_001002814.3; = p.S580R on NM_025151.5) | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.283); catalogued as COSV54762439; called by muse, mutect2, varscan2
- RAD21 | c.874G>C p.D292H | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52057344; called by muse, mutect2, varscan2
- RANBP2 | c.2615G>C p.G872A | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs373286631, COSV51705477; called by muse, mutect2, varscan2
- RBM17 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV65914524; called by muse, mutect2
- RBMX | c.743A>G p.H248R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV57810623; called by muse, mutect2, varscan2
- REG3A | c.76+1G>T p.X26_splice | Splice Site (SNP) | VAF 9/47 reads (19%) | catalogued as COSV59410743; called by muse, mutect2, varscan2
- REXO1 | c.1963C>G p.L655V | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50084308; called by muse, mutect2, varscan2
- RFC2 | c.176G>C p.R59T | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV50016605; called by muse, mutect2, varscan2
- RGS22 | c.1208C>G p.S403C | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV62665169; called by muse, mutect2
- RIPK2 | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55131599; called by muse, mutect2
- RNF220 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.935); catalogued as COSV62408267; called by muse, mutect2, varscan2
- RPGR | c.2434G>C p.E812Q (on ENST00000339363 / NM_001367249.1; = p.E607Q on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV58837741; called by muse, mutect2, varscan2
- RPL10A | c.618C>G p.I206M | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV57690654; called by muse, mutect2, varscan2
- RPTOR | c.1043G>C p.R348P | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60804798, COSV60814028; called by muse, mutect2
- RRP15 | c.85G>T p.G29* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100860776; called by muse, mutect2, varscan2
- RRP36 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55065232; called by muse, varscan2
- RTEL1 | c.2935C>T p.R979W | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.394); catalogued as rs144034326; called by muse, mutect2, varscan2
- RTL6 | c.719A>T p.*240Lext*7 | Nonstop Mutation (SNP) | VAF 28/164 reads (17%) | catalogued as COSV100373835; called by muse, mutect2, varscan2
- RYR1 | c.7208G>A p.R2403H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as rs749136416, COSV62087171; called by muse, mutect2, varscan2
- SAMD9L | c.1551G>T p.W517C | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59083715; called by muse, mutect2
- SAYSD1 | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as COSV57723396; called by muse, mutect2, varscan2
- SCARF2 | c.1610C>G p.S537* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99839379; called by muse, mutect2, varscan2
- SCN10A | c.3514G>C p.E1172Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71862306; called by muse, mutect2, varscan2
- SCRN2 | c.691T>G p.S231A | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV51636848; called by muse, mutect2
- SCYL2 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV62569961; called by muse, mutect2
- SEPTIN4 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.033); catalogued as COSV58727538, COSV58728682; called by muse, mutect2
- SEPTIN7 | c.902C>A p.T301N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63255986; called by muse, mutect2, varscan2
- SHOC1 | c.3650A>G p.Y1217C | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV59505067; called by muse, mutect2, varscan2
- SHPRH | c.2887G>A p.D963N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51614698; called by muse, mutect2, varscan2
- SLC9B1 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV56473340; called by muse, mutect2, varscan2
- SLX4 | c.3131G>T p.S1044I | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1454172454, COSV53566604; called by muse, mutect2, varscan2
- SMARCA4 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV60803632, COSV60806378; called by muse, mutect2, varscan2
- SMARCD1 | c.1250T>C p.I417T | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67412772; called by muse, mutect2, varscan2
- SMPD3 | c.1515C>G p.D505E | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54714260; called by muse, mutect2, varscan2
- SNAI1 | c.396G>T p.L132F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54864681; called by muse, mutect2, varscan2
- SORCS3 | c.3491A>T p.E1164V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63818393; called by muse, mutect2, varscan2
- SPEN | c.9019A>C p.I3007L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV65365435; called by muse, mutect2, varscan2
- SPOPL | c.964A>G p.I322V | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.143); catalogued as COSV54515075; called by muse, mutect2, varscan2
- SPTA1 | c.5903C>T p.A1968V | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as COSV63752366, COSV63757063; called by muse, mutect2
- SRCAP | c.759G>C p.Q253H | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV52677558; called by muse, mutect2, varscan2
- STT3A | c.1451C>G p.S484C | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67065259; called by muse, mutect2
- STT3B | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV55504637; called by muse, mutect2
- SVOPL | c.507C>A p.Y169* (on ENST00000419765; = p.Y17* on NM_174959.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/146 reads (10%) | catalogued as COSV99939449, COSV99939503; called by muse, mutect2
- SYNE1 | c.24055G>A p.E8019K (on ENST00000367255 / NM_182961.4; = p.E7948K on NM_033071.3) | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54934485; called by mutect2, varscan2
- SYNE1 | c.11788G>C p.E3930Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV55048488; called by muse, mutect2, varscan2
- SYNE3 | c.135G>A p.W45* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100516267; called by muse, mutect2, varscan2
- SYNJ1 | c.3193C>T p.L1065F | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV59153085; called by muse, mutect2
- TAF1L | c.5410G>A p.G1804R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.157); catalogued as COSV54265862; called by muse, mutect2, varscan2
- TBC1D15 | c.1989G>T p.L663F | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.068); catalogued as COSV59851477; called by muse, mutect2, varscan2
- TDRD7 | c.3263C>G p.S1088* | Nonsense Mutation (SNP) | VAF 9/102 reads (9%) | catalogued as COSV100795740; called by muse, mutect2
- TECTA | c.3136G>A p.A1046T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV50759276; called by muse, mutect2, varscan2
- TEX15 | c.910G>T p.E304* (on ENST00000256246; = p.E687* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99821785; called by muse, mutect2, varscan2
- THAP7 | c.324_325del p.H108Qfs*8 | Frame Shift Del (DEL) | VAF 19/120 reads (16%) | catalogued as rs769627012; called by pindel, varscan2
- THRA | c.160G>T p.V54F | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.993); catalogued as COSV52844953; called by muse, mutect2, varscan2
- THRAP3 | c.685G>C p.G229R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV100663472; called by muse, mutect2, varscan2
- THSD1 | c.1675C>A p.L559M | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.786); catalogued as COSV51630374; called by muse, mutect2
- THSD4 | c.1951G>C p.E651Q | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.309); catalogued as COSV55978089; called by muse, mutect2
- TJP3 | c.1879G>A p.V627M | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs955970013, COSV53664453; called by muse, mutect2, varscan2
- TMEM176B | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100423539, COSV58440482; called by muse, mutect2, varscan2
- TNFRSF10B | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV99375513; called by muse, mutect2
- TRAPPC11 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV100591883, COSV58218061; called by muse, mutect2
- TRIP11 | c.2778G>T p.K926N | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.549); catalogued as COSV50942369; called by muse, mutect2
- TRRAP | c.158C>A p.T53K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100723341, COSV62850594; called by muse, mutect2, varscan2
- TUBA1A | c.262C>A p.H88N | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV55498450; called by muse, mutect2
- TVP23A | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51594825; called by muse, mutect2
- TXLNB | c.1393G>T p.E465* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100625089, COSV64443688; called by muse, mutect2, varscan2
- UBA6 | c.1549A>G p.I517V | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.894); catalogued as rs1447762391, COSV59179686; called by muse, mutect2, varscan2
- UBE2K | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV54692085; called by muse, mutect2
- VARS2 | c.1266G>T p.M422I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.124); catalogued as COSV58913783; called by muse, mutect2, varscan2
- VPS13D | c.3727G>T p.G1243C | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV50660928; called by muse, mutect2, varscan2
- WDR62 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54337646; called by muse, mutect2, varscan2
- WDR90 | c.4807G>A p.V1603I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.046); catalogued as rs758287350, COSV53468472, COSV53468939; called by mutect2, varscan2
- XKRX | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV60708807; called by muse, mutect2, varscan2
- YBX3 | c.1027A>G p.N343D | Missense Mutation (SNP) | VAF 87/290 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54386432; called by muse, mutect2, varscan2
- ZFHX4 | c.8546C>G p.P2849R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV51479016; called by muse, mutect2, varscan2
- ZFHX4 | c.8718C>A p.D2906E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51479057; called by muse, mutect2, varscan2
- ZFP2 | c.1366C>A p.H456N | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV63726449; called by muse, mutect2, varscan2
- ZFPL1 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs1401917372, COSV51870425; called by muse, mutect2, varscan2
- ZFY | c.2068C>A p.H690N | Missense Mutation (SNP) | VAF 85/111 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50083829; called by muse, mutect2, varscan2
- ZIC5 | c.1642G>T p.D548Y | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57438496, COSV57439137; called by muse, mutect2
- ZNF155 | c.557G>A p.C186Y | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.864); catalogued as rs1294152628, COSV54207924; called by muse, mutect2, varscan2
- ZNF180 | c.1784A>G p.H595R | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55422910; called by muse, mutect2, varscan2
- ZNF284 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV69691440; called by muse, mutect2
- ZNF287 | c.1825C>T p.Q609* | Nonsense Mutation (SNP) | VAF 7/73 reads (10%) | catalogued as COSV101209393; called by muse, mutect2, varscan2
- ZNF451 | c.947A>G p.K316R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as COSV62598903; called by muse, mutect2, varscan2
- ZNF540 | c.1784G>C p.R595T | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57110614; called by muse, mutect2
- ZNF558 | c.1082C>G p.S361* | Nonsense Mutation (SNP) | VAF 26/96 reads (27%) | catalogued as COSV100037989; called by muse, mutect2, varscan2
- ZNF558 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV56863988; called by muse, mutect2, varscan2
- ZNF569 | c.1093C>A p.Q365K | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.835); catalogued as COSV57596300, COSV57597519; called by muse, mutect2, varscan2
- ZNF571 | c.1321C>G p.H441D | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs958974150, COSV60734224; called by muse, mutect2
- ZNF813 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.013); catalogued as COSV67177457; called by muse, mutect2, varscan2
- ZNF98 | c.30G>T p.M10I | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV63338399; called by muse, mutect2, varscan2
- FCGBP | c.8912G>C p.G2971A | Missense Mutation (SNP) | VAF 42/424 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); called by muse, mutect2
- GAS2L2 | c.1619C>A p.A540D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GTF2H2B | n.755C>A | Splice Region (SNP) | VAF 10/85 reads (12%) | called by mutect2, varscan2
- GTSE1 | c.1621dup p.L541Pfs*27 | Frame Shift Ins (INS) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- IGHV3-38 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- KLB | c.2897dup p.F967Lfs*4 | Frame Shift Ins (INS) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- KNTC1 | c.4759_4760del p.A1587Pfs*3 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- OR5A1 | c.130_141del p.W44_A47del | In Frame Del (DEL) | VAF 16/116 reads (14%) | called by mutect2, varscan2
- OR5AC2 | c.736del p.H246Ifs*12 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- OR8G1 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- SPTAN1 | c.783C>A p.N261K | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.597); called by muse, mutect2
- ZNF292 | c.3028del p.T1010Lfs*4 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- ZNF827 | c.1614G>C p.L538F | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); called by muse, mutect2
- ZNF84 | c.1439C>G p.T480S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- AGAP2 | c.3108C>G p.A1036= (on ENST00000547588 / NM_001122772.2; = p.A680= on NM_014770.4) | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV57730395; called by muse, mutect2, varscan2
- AKAP6 | c.1704G>A p.L568= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV55224561; called by muse, mutect2
- ALDH5A1 | c.900G>T p.V300= | Silent (SNP) | VAF 11/156 reads (7%) | catalogued as COSV100708928, COSV62374220; called by muse, mutect2
- ARHGAP29 | c.2052C>T p.I684= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV53114812; called by muse, mutect2, varscan2
- ARHGEF5 | c.4596G>A p.E1532= | Silent (SNP) | VAF 11/189 reads (6%) | catalogued as rs894935120, COSV50214744; called by muse, mutect2
- BNC1 | c.2412C>A p.A804= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV61758483; called by muse, mutect2, varscan2
- C12orf57 | c.33G>A p.L11= | Silent (SNP) | VAF 8/162 reads (5%) | catalogued as rs782168213, COSV57547320; called by muse, mutect2
- C17orf50 | c.438G>A p.R146= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs781829396; called by muse, mutect2
- CD109 | c.894G>A p.E298= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV99754107; called by muse, mutect2
- CD1C | c.732G>A p.Q244= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV63807090; called by muse, mutect2
- CDCA5 | c.501C>T p.G167= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV51870408; called by muse, mutect2, varscan2
- CLCA2 | c.1959G>A p.T653= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs369158144, COSV65285849; called by mutect2, varscan2
- CLCN3 | c.2286G>T p.V762= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV61628006; called by muse, mutect2, varscan2
- CLYBL | c.948G>C p.G316= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV59225717; called by muse, mutect2, varscan2
- CPA4 | c.120G>A p.L40= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as COSV55984392; called by muse, varscan2
- DAXX | c.2148G>A p.R716= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV56471503; called by muse, mutect2, varscan2
- DAZAP1 | c.513C>A p.V171= | Silent (SNP) | VAF 12/262 reads (5%) | catalogued as COSV51835175; called by muse, mutect2
- DCAF7 | c.81G>T p.R27= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs371085501, COSV100121157; called by muse, mutect2, varscan2
- DRP2 | c.1287C>T p.I429= | Silent (SNP) | VAF 60/98 reads (61%) | catalogued as COSV65811191; called by muse, mutect2, varscan2
- EDC4 | c.1752G>C p.L584= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV62767119; called by muse, mutect2
- FETUB | c.720T>C p.S240= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV54006600; called by muse, mutect2, varscan2
- FMO2 | c.1338G>A p.K446= | Silent (SNP) | VAF 50/262 reads (19%) | catalogued as COSV52949353; called by muse, mutect2, varscan2
- FOXN3 | c.30G>A p.K10= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV54313674; called by muse, mutect2, varscan2
- FRMD8 | c.156C>G p.L52= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV58213361; called by muse, mutect2, varscan2
- GRAMD1C | c.420C>G p.L140= | Silent (SNP) | VAF 17/155 reads (11%) | catalogued as COSV63983562; called by muse, mutect2
- HACL1 | c.288A>T p.A96= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100337301; called by muse, mutect2
- HECTD4 | c.9525C>T p.L3175= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV66396494; called by muse, mutect2, varscan2
- HIPK2 | c.1683G>C p.V561= | Silent (SNP) | VAF 19/212 reads (9%) | catalogued as COSV61230924; called by muse, mutect2
- INTS7 | c.852A>G p.P284= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV65343768; called by muse, mutect2
- ITPR3 | c.123G>A p.A41= | Silent (SNP) | VAF 40/198 reads (20%) | catalogued as rs777701344, COSV65412756; called by muse, mutect2, varscan2
- KCNH1 | c.1206C>T p.D402= (on ENST00000271751 / NM_172362.3; = p.D375= on NM_002238.4) | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV55070435, COSV55093704; called by muse, mutect2, varscan2
- KCNH2 | c.2160C>T p.F720= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV51213883; called by muse, mutect2
- KHNYN | c.759C>T p.Y253= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs543713419, COSV52162315; called by mutect2, varscan2
- KIF19 | c.129T>C p.V43= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV100739125; called by muse, mutect2
- KRT28 | c.960G>A p.L320= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV60685964; called by muse, mutect2
- LIPF | c.576C>T p.I192= | Silent (SNP) | VAF 24/258 reads (9%) | catalogued as COSV53285464; called by muse, mutect2
- MAEA | c.600C>G p.L200= (on ENST00000303400 / NM_001017405.3; = p.L159= on NM_005882.5) | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV53263894; called by muse, mutect2, varscan2
- MBNL3 | c.576G>A p.E192= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV63731371; called by muse, mutect2, varscan2
- MDN1 | c.1026A>G p.L342= | Silent (SNP) | VAF 13/188 reads (7%) | catalogued as rs1258126250, COSV65526404; called by muse, mutect2
- MEX3B | c.612G>T p.V204= | Silent (SNP) | VAF 37/133 reads (28%) | catalogued as rs180699460, COSV61663959; called by muse, mutect2, varscan2
- MIPEP | c.1659G>C p.L553= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV66301473; called by muse, mutect2, varscan2
- MST1R | c.1911G>A p.E637= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs751662055, COSV99619211; called by mutect2, varscan2
- MUC16 | c.13293C>A p.L4431= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV67481083, COSV67491371; called by muse, mutect2, varscan2
- NAV1 | c.3081C>T p.G1027= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV55222361; called by muse, mutect2, varscan2
- NRG3 | c.1974C>A p.V658= (on ENST00000404547 / NM_001370084.1; = p.V634= on NM_001010848.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV64549093, COSV64575564; called by muse, mutect2, varscan2
- NTRK3 | c.213C>T p.I71= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV58133847; called by muse, mutect2
- NUMA1 | c.750G>A p.Q250= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV61188687; called by muse, mutect2, varscan2
- NYAP2 | c.768C>T p.F256= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as COSV56011985; called by muse, mutect2
- OR52H1 | c.681C>G p.V227= (on ENST00000322653; = p.V233= on NM_001005289.1) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV59505962; called by muse, mutect2
- OR8H3 | c.60C>T p.D20= | Silent (SNP) | VAF 18/198 reads (9%) | catalogued as rs576460980, COSV57910368; called by muse, mutect2
- P3H1 | c.711G>C p.V237= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV52535865; called by muse, mutect2, varscan2
- PAQR5 | c.402C>T p.Y134= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs781740880, COSV61818675; called by muse, mutect2, varscan2
- PLEKHF1 | c.162C>T p.I54= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as COSV101460744, COSV71410261; called by muse, mutect2
- POLR2G | c.291C>G p.L97= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as COSV57135514; called by muse, mutect2, varscan2
- PPP4R3B | c.555A>T p.L185= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV55407522; called by muse, mutect2, varscan2
- PSMB4 | c.438G>A p.S146= | Silent (SNP) | VAF 13/230 reads (6%) | catalogued as rs1176744494, COSV51852594; called by muse, mutect2
- PTCH2 | c.837G>C p.L279= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100942206; called by muse, mutect2
- RAB39A | c.288T>A p.T96= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV57695248; called by muse, mutect2, varscan2
- RAD23A | c.243C>A p.A81= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs527707600, COSV57131812; called by muse, mutect2, varscan2
- RNF207 | c.930G>C p.L310= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100933733, COSV100933746; called by muse, mutect2
- RPIA | c.750G>C p.V250= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV52170964, COSV52171438; called by muse, mutect2, varscan2
- RRP15 | c.417G>A p.R139= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV65118440; called by muse, mutect2, varscan2
- SHANK1 | c.6180G>T p.G2060= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99521639; called by muse, mutect2
- SIN3B | c.1044C>A p.V348= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV56135059; called by muse, mutect2, varscan2
- SLC25A24 | c.948G>A p.L316= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV51449381; called by muse, mutect2, varscan2
- SPATA2L | c.363G>T p.L121= | Silent (SNP) | VAF 22/253 reads (9%) | catalogued as rs1006325527, COSV57048093; called by muse, mutect2
- SPECC1L | c.2532C>T p.L844= | Silent (SNP) | VAF 21/135 reads (16%) | catalogued as COSV58660323; called by muse, mutect2, varscan2
- STK25 | c.57C>A p.L19= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV57262621, COSV57264165; called by muse, mutect2, varscan2
- SUV39H1 | c.901C>T p.L301= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as COSV61921116; called by muse, mutect2, varscan2
- TBC1D9B | c.3630G>A p.E1210= (on ENST00000356834 / NM_198868.3; = p.E1193= on NM_015043.4) | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs769621024, COSV52974423; called by muse, mutect2, varscan2
- TBX22 | c.198C>T p.P66= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV64787158; called by muse, mutect2, varscan2
- TCIRG1 | c.1917G>C p.L639= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99693504; called by muse, mutect2
- TECPR1 | c.483G>A p.R161= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV65784416; called by muse, mutect2, varscan2
- TIAM2 | c.3510C>T p.D1170= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV51642967; called by muse, mutect2, varscan2
- TNXB | c.4980C>A p.P1660= (on ENST00000647633; = p.P1413= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV64484504; called by muse, mutect2
- TREML2 | c.192G>A p.E64= | Silent (SNP) | VAF 39/162 reads (24%) | catalogued as rs555770440, COSV72439209; called by muse, mutect2, varscan2
- TRMT10A | c.606C>G p.A202= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV56745766; called by muse, mutect2, varscan2
- TTBK1 | c.795G>T p.P265= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV52494481; called by muse, mutect2, varscan2
- UBXN2B | c.828A>G p.T276= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV68309409; called by muse, mutect2, varscan2
- USP3 | c.1476G>C p.L492= | Silent (SNP) | VAF 60/171 reads (35%) | catalogued as COSV51428883; called by muse, mutect2, varscan2
- ZDHHC1 | c.1242C>A p.P414= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs1567513780, COSV99339534; called by muse, mutect2, varscan2
- ZFYVE1 | c.1017C>T p.L339= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV59612150; called by muse, mutect2, varscan2
- ZNF320 | c.1438C>T p.L480= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV67088618; called by muse, mutect2
- ZNF560 | c.315A>T p.I105= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV100038818; called by muse, mutect2
- ZNF816 | c.627G>A p.K209= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV54411946; called by muse, mutect2, varscan2
- ZP4 | c.849C>G p.V283= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV63912903; called by muse, mutect2, varscan2
- ZSCAN31 | c.321G>T p.G107= | Silent (SNP) | VAF 12/241 reads (5%) | catalogued as COSV60181405; called by muse, mutect2
- ZZZ3 | c.1836G>A p.K612= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV66234507; called by muse, mutect2
- CKAP5 | c.4027+185A>T | Intron (SNP) | VAF 40/144 reads (28%) | catalogued as COSV100371093; called by muse, mutect2, varscan2
- CNOT1 | c.3523-861G>A | Intron (SNP) | VAF 28/72 reads (39%) | catalogued as COSV99800733; called by muse, mutect2, varscan2
- CNR1 | c.*2C>T | 3'UTR (SNP) | VAF 12/176 reads (7%) | catalogued as COSV100759272; called by muse, mutect2
- CSMD3 | c.178+59905G>C | Intron (SNP) | VAF 10/73 reads (14%) | catalogued as COSV52258677, COSV99841494; called by muse, mutect2, varscan2
- DCHS2 | n.2679G>T | RNA (SNP) | VAF 4/40 reads (10%) | catalogued as COSV59734373; called by mutect2, varscan2
- FAM193B | c.1275+983T>A | Intron (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100286704; called by muse, mutect2
- MIR520E | n.75T>C | RNA (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- MIR526B | n.5G>T | RNA (SNP) | VAF 6/59 reads (10%) | called by mutect2, varscan2
- MIR654 | n.17G>A | RNA (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- PCDHA3 | c.2394+65C>G | Intron (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100793597, COSV100793681; called by muse, mutect2
- SNORD114-26 | n.42A>G | RNA (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- THSD4 | c.1016-70346C>G | Intron (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
